Surgical pathology report (de-identified scan), TCGA case TCGA-FB-AAPS, project TCGA-PAAD (Pancreatic Adenocarcinoma), tissue source site Asterand, specimen TCGA-FB-AAPS-01A (Primary Tumor).

[page 1 of 3]
TSS Patient ID:

Surgical Date:

Gross Description: D: Whipple (paired silk prior pancreatic margin, long single silk portal vein, long single blue SMA margin, looped blue suture deep radial margin):

Received is a Whipple specimen that comprises a pancreas, duodenum, and gallbladder. The specimen is oriented by the surgeon with a paired silk suture designated as prior pancreatic margin, a long single silk suture designated as portal vein, a long single blue suture designated as superior mesenteric artery margin, and a looped blue suture designated as deep radial margin.

The pancreas measures 5.5 x 5.5 x 4 cm. The neck margin is inked blue and the radial margin is inked black. The pancreas is sectioned to reveal an ill-defined, indurated, white-yellow mass that measures 3 x 3 x 2.7 cm that abuts and possibly invades the common bile duct, is less than 0.1 cm to the superior mesenteric artery margin, and less than 0.1 cm to the deep radial margin, less than 0.4 cm to the portal vein margin, and greater than 2 cm from the pancreatic neck margin. The common bile duct and pancreatic duct are both probe patent. The remaining pancreatic parenchyma is tan-yellow with normal lobular architecture. The duodenum measures 19.5 cm in length x 3.3 cm in diameter and has smooth, red-purple serosa. Both ends are stapled shut. The staples are inked and opened to reveal a tan-brown mucosal surface with normal appearing longitudinal folds. The distal 6.5 cm of duodenum is dark brown and focally hemorrhagic with a slightly dusky appearance. There is an ill-defined, erythematous lesion at the opening of the pancreatic duct in

ICD-O-3

Adenocarcinoma, ductal
8500/3

Site: Pancreas head
C25.0

Op 5/16/14

[page 2 of 3]
the duodenum that measures approximately 2 x 1 cm in circumference. The remaining duodenal mucosa is unremarkable. No other masses or lesions are identified.

The gallbladder measures 10.2 x 4.2 x 1.6 cm and has a smooth-to-roughened, red-tan serosal surface. The gallbladder is opened and is filled with viscous, red-black bile fluid. A cystic duct remnant is identified and measures 1.5 cm in length x 0.4 cm in diameter. The serosal surface is bile-stained and grossly unremarkable. In addition, there is a crystallized calculus, 1.5 cm in greatest dimension, identified. No masses or lesions are identified.

The pancreatic duct and common bile duct enter the duodenum at different locations approximately 1.5 cm apart from each other.

Sectioning through the fat closely reveals five possible lymph nodes. The largest measures

1.5 cm in greatest dimension

Representative sections are submitted.

Microscopic Description:

Diagnosis Details: SOURCE OF SPECIMEN:A Common bile duct - FS

SOURCE OF SPECIMEN:B Gastroduodenal lymph node

SOURCE OF SPECIMEN:C Pancreatic neck margin - FS

SOURCE OF SPECIMEN:D Whipple

Final Pathologic Diagnosis:

A: Common bile duct, biopsy: - Bile duct, negative for malignancy

[page 3 of 3]
B: Gastroduodenal lymph node, biopsy: - Two lymph nodes, negative for malignancy (0/2)

C: Pancreatic neck margin, biopsy: - Pancreas, negative for malignancy

D: Pancreas, duodenum, and gallbladder, Whipple procedure: - Ductal adenocarcinoma of the head of pancreas, moderately differentiated

Comments:

Formatted Path Reports: PANCREAS TISSUE CHECKLIST

Specimen type: Pancreatoduodenectomy

Tumor site: Head

Tumor size: 3 x 3 x 2.7 cm

Histologic type: Adenocarcinoma, ductal type

Histologic grade: Moderately differentiated

Tumor extent: Not specified

Lymph nodes: 1/7 positive for metastasis (Regional 1/7)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Not specified

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

Source: NCI Genomic Data Commons file e234e633-22cb-4a3d-876b-b3aafe031052 (TCGA-FB-AAPS.0369BABC-3B58-4386-9CF6-71889B1F651B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).